Somatic mutation profile of tumor specimen TARGET-30-PATVWA-01A (aliquot TARGET-30-PATVWA-01A-01D) from TARGET case TARGET-30-PATVWA, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.2 years (1,533 days).
Specimen TARGET-30-PATVWA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e6bcf44-3cb3-4ed5-91b2-183543ab3d5e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATVWA-10A (Blood Derived Normal), aliquot TARGET-30-PATVWA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a127ea41-713c-4e1d-8601-5d5f6715a665

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATN1 | c.1528C>G p.P510A | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.096); catalogued as COSV63110316; called by muse, mutect2, varscan2
- DPP6 | c.1519G>A p.D507N (on ENST00000377770 / NM_001364500.2; = p.D445N on NM_001936.5) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1461422075, COSV59599682; called by muse, mutect2, varscan2
